Somatic mutation profile of tumor specimen TCGA-EB-A551-01A (aliquot TCGA-EB-A551-01A-21D-A27K-08) from TCGA case TCGA-EB-A551, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Amelanotic melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 78.5 years (28,671 days).
Specimen TCGA-EB-A551-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36c1267e-5bbd-4b40-87df-f1bbb7f6dd8d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A551-10A (Blood Derived Normal), aliquot TCGA-EB-A551-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/506dcede-056d-4b65-a9ba-9172493807a9

The open-access MAF lists 408 somatic variants for this specimen: 265 protein-altering or splice-affecting, 137 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 240, Silent 137, Nonsense Mutation 16, Splice Site 5, 5'Flank 2, 3'Flank 2, Splice Region 1, RNA 1, Translation Start Site 1, Frame Shift Del 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAG1 | c.1528C>T p.Q510* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as rs1568796158, CM061803, COSV54754130; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 39/145 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABCA2 | c.2783C>T p.T928I (on ENST00000614293; = p.T898I on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV55798253; called by muse, mutect2, varscan2
- ACD | c.1295C>T p.P432L (on ENST00000620338; = p.P343L on NM_022914.3) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54666261; called by muse, mutect2, varscan2
- ADAMTS16 | c.1778C>A p.S593Y | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56980646, COSV56982257; called by muse, mutect2, varscan2
- ADAMTS20 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs772637638, COSV67127980; called by muse, mutect2, varscan2
- ADAMTS9 | c.5411C>T p.P1804L | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55776310; called by muse, mutect2, varscan2
- ADGRA1 | c.133G>C p.A45P | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV66924932, COSV66925202; called by muse, mutect2, varscan2
- ADH1C | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 36/275 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1005267020, COSV72463393; called by muse, mutect2, varscan2
- AKAP13 | c.4316G>A p.S1439N | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs373476329, COSV63450262; called by muse, mutect2, varscan2
- ALKBH3 | c.376A>G p.T126A | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV57023235; called by muse, mutect2, varscan2
- ALMS1 | c.8227A>G p.T2743A | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.399); catalogued as COSV52504250; called by muse, mutect2, varscan2
- ALPK3 | c.2216C>T p.P739L | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV51930624; called by muse, mutect2, varscan2
- ANK3 | c.8626C>T p.H2876Y | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as COSV55047196, COSV55048368; called by muse, mutect2, varscan2
- ANKS1B | c.1487G>A p.R496K | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.173); catalogued as COSV61337993; called by muse, mutect2, varscan2
- ARHGEF17 | c.3496G>A p.D1166N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.946); catalogued as rs780905191, COSV55230187; called by muse, mutect2, varscan2
- ARHGEF19 | c.1933C>T p.H645Y | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV54615382; called by muse, mutect2, varscan2
- ARHGEF5 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV50208036; called by mutect2, varscan2
- ARMC5 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs747183399, CD1312676, COSV51655083, COSV51655149; called by muse, mutect2, varscan2
- ATOH7 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV65447607; called by muse, mutect2, varscan2
- ATP6V1E2 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.78); catalogued as rs149758859, COSV60575707; called by muse, mutect2, varscan2
- ATP9A | c.327+2T>A p.X109_splice | Splice Site (SNP) | VAF 12/66 reads (18%) | catalogued as COSV58763934; called by muse, mutect2, varscan2
- BBX | c.2659A>T p.T887S (on ENST00000325805 / NM_001142568.3; = p.T857S on NM_020235.7) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as rs147247035; called by muse, mutect2, varscan2
- BOC | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV56347759; called by muse, mutect2, varscan2
- BRD7 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as COSV101164741, COSV67158378; called by muse, mutect2, varscan2
- BRD9 | c.1346G>C p.G449A | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.136); catalogued as COSV60245024; called by muse, mutect2, varscan2
- BRINP3 | c.2188C>T p.H730Y | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV66515112; called by muse, mutect2, varscan2
- BSN | c.9913C>T p.L3305F | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as rs1278854486, COSV56513899; called by muse, mutect2, varscan2
- C7 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV57471726; called by muse, mutect2, varscan2
- C8A | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV63483275; called by muse, mutect2, varscan2
- C8B | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.783); catalogued as rs867837249, COSV64776574; called by muse, mutect2, varscan2
- C9orf131 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.135); catalogued as COSV56609863; called by muse, mutect2, varscan2
- CALCR | c.466C>T p.H156Y | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs267601639, COSV64006235; called by muse, mutect2, varscan2
- CAPN6 | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60694088; called by muse, mutect2, varscan2
- CARD11 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as COSV67797402; called by muse, mutect2
- CCDC141 | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs757376410, COSV55369931, COSV55371854; called by muse, mutect2, varscan2
- CCDC158 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as rs370067451; called by muse, mutect2, varscan2
- CD163 | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.115); catalogued as COSV63130159; called by muse, mutect2, varscan2
- CDH12 | c.1879C>T p.L627F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1425273193, COSV66390358; called by mutect2, varscan2
- CFAP57 | c.1679T>C p.V560A | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as COSV65263795; called by muse, mutect2, varscan2
- CHD7 | c.2345C>T p.S782F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV71107567; called by muse, mutect2, varscan2
- CNTNAP2 | c.2215C>T p.P739S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.87); PolyPhen benign (0.009); catalogued as rs267601388, COSV62143231, COSV62177141; called by muse, mutect2, varscan2
- CNTNAP2 | c.3747A>C p.Q1249H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV62151181; called by muse, mutect2
- COL22A1 | c.2339G>A p.G780E | Missense Mutation (SNP) | VAF 44/299 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57326600; called by muse, mutect2, varscan2
- CPPED1 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267604414, COSV55496027; called by muse, mutect2, varscan2
- CPXM2 | c.2138G>A p.R713K | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.102); catalogued as rs749176185, COSV99581008; called by muse, mutect2, varscan2
- CSMD3 | c.10964G>A p.R3655K (on ENST00000297405 / NM_001363185.1; = p.R3486K on NM_052900.3) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV52116881; called by muse, mutect2, varscan2
- CTRC | c.135C>T p.I45= | Splice Region (SNP) | VAF 6/50 reads (12%) | catalogued as COSV65621235; called by muse, mutect2, varscan2
- CYP4A11 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV60222391; called by muse, mutect2, varscan2
- DDX17 | c.864T>G p.I288M | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.105); catalogued as COSV53250977; called by muse, mutect2, varscan2
- DEPDC4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 21/100 reads (21%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.005); catalogued as rs764815513, COSV54553194; called by muse, mutect2, varscan2
- DLG2 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.685); catalogued as rs773631287, COSV54626227; called by muse, mutect2, varscan2
- DMBT1 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 109/452 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.412); catalogued as rs1243557690, COSV57536590; called by muse, mutect2, varscan2
- DMRT1 | c.866G>A p.R289K | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs757552219, COSV66519329; called by muse, mutect2, varscan2
- DMRTC2 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as rs141103699; called by muse, mutect2, varscan2
- DMXL1 | c.3976C>T p.H1326Y | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100223199; called by muse, mutect2, varscan2
- DNAH2 | c.12158G>A p.W4053* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as COSV101208983; called by muse, mutect2, varscan2
- DNAH2 | c.12159G>A p.W4053* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as COSV101208985, COSV101209095; called by muse, mutect2, varscan2
- DNAI2 | c.1445C>T p.S482L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs187581577; called by muse, mutect2
- DNAJC14 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV57912348; called by muse, mutect2
- DPM3 | c.241G>T p.A81S (on ENST00000341298; = p.A111S on NM_018973.3) | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57596317; called by muse, mutect2, varscan2
- DSC2 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs769576778, COSV51861904; called by mutect2, varscan2
- DYNAP | c.124G>A p.E42K (on ENST00000321600; = p.E16K on NM_173629.3) | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.423); catalogued as COSV58666097; called by muse, mutect2, varscan2
- DYRK3 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV65605481; called by muse, mutect2, varscan2
- EIF2A | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as COSV56405391; called by muse, mutect2
- EPHB1 | c.2284G>A p.D762N | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV67653779; called by muse, mutect2, varscan2
- EPSTI1 | c.845G>A p.R282K (on ENST00000398762 / NM_001330543.2; = p.R271K on NM_033255.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.047); catalogued as COSV58044210; called by muse, mutect2, varscan2
- FAM124B | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs1175999794, COSV66271353; called by muse, mutect2, varscan2
- FANK1 | c.866A>T p.N289I | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV64125177; called by muse, mutect2, varscan2
- FAT1 | c.3832G>A p.D1278N | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767041778, COSV71672328; called by muse, mutect2, varscan2
- FBN2 | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV52496739; called by muse, mutect2, varscan2
- FBXO38 | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57026160; called by muse, mutect2, varscan2
- FGFR1 | c.2187-1G>A p.X729_splice (on ENST00000447712 / NM_023110.3; = p.X727_splice on NM_015850.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as COSV58329513; called by muse, mutect2, varscan2
- FGFR2 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as rs1207716999, COSV60641394; called by muse, mutect2, varscan2
- FLG | c.10964G>A p.G3655E | Missense Mutation (SNP) | VAF 84/318 reads (26%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.982); catalogued as COSV100910469; called by mutect2, varscan2
- FLG | c.10963G>A p.G3655R | Missense Mutation (SNP) | VAF 104/516 reads (20%) | SIFT tolerated (1); PolyPhen probably damaging (0.993); catalogued as rs1557870449, COSV100910470; called by muse, mutect2, varscan2
- FLG | c.6187G>A p.G2063R | Missense Mutation (SNP) | VAF 105/442 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs749273002, COSV64237839; called by muse, mutect2, varscan2
- FLG2 | c.6638C>T p.S2213F | Missense Mutation (SNP) | VAF 80/443 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV66167048; called by muse, mutect2, varscan2
- FLYWCH1 | c.728A>G p.E243G (on ENST00000253928 / NM_001308068.2; = p.E242G on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV54143850; called by muse, mutect2
- FMN2 | c.4952T>C p.L1651P | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as COSV60419902; called by muse, mutect2, varscan2
- FMNL3 | c.3077C>T p.P1026L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99525575; called by muse, mutect2
- FNDC3A | c.101T>C p.V34A | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65694771; called by muse, mutect2, varscan2
- FOCAD | c.2999C>T p.S1000F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV58094600; called by mutect2, varscan2
- FREM2 | c.4932G>A p.M1644I | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as rs754062156, COSV54830412; called by muse, mutect2, varscan2
- FRMD5 | c.1066A>G p.T356A | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV68720633; called by muse, mutect2, varscan2
- FRMPD4 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV101042108; called by muse, mutect2, varscan2
- FYB1 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs746531540, COSV60941976; called by muse, mutect2, varscan2
- GABRA1 | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.232); catalogued as COSV50099283; called by muse, mutect2, varscan2
- GAD1 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV60151697; called by muse, mutect2, varscan2
- GAD1 | c.764C>G p.S255C | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60151706; called by muse, mutect2, varscan2
- GAK | c.3853G>A p.E1285K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780851771, COSV58503222; called by muse, mutect2, varscan2
- GALNT14 | c.370C>A p.R124S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61103131; called by muse, mutect2, varscan2
- GDF3 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61711934; called by muse, mutect2, varscan2
- GDPD2 | c.1210G>A p.G404R | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV65532155; called by muse, mutect2, varscan2
- GGN | c.1782C>A p.C594* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as COSV53056195; called by muse, mutect2, varscan2
- GIMAP2 | c.108T>G p.S36R | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201164211, COSV56234607; called by muse, mutect2, varscan2
- GLIS3 | c.2122C>T p.P708S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.722); catalogued as COSV60924898; called by muse, mutect2, varscan2
- GPR151 | c.198G>A p.W66* | Nonsense Mutation (SNP) | VAF 11/70 reads (16%) | catalogued as COSV99694365; called by muse, mutect2, varscan2
- GPR151 | c.197G>A p.W66* | Nonsense Mutation (SNP) | VAF 11/72 reads (15%) | catalogued as rs1288455444, COSV99694366; called by muse, mutect2, varscan2
- GPR156 | c.2111G>A p.R704Q | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs761772174, COSV59938378; called by muse, varscan2
- GSDMC | c.461A>G p.N154S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs766304265, COSV52693688; called by muse, mutect2, varscan2
- HCN4 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56081800, COSV99984168; called by muse, mutect2, varscan2
- HEPH | c.379C>T p.P127S (on ENST00000343002; = p.P181S on NM_138737.5) | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1188793883, COSV57960129; called by muse, mutect2, varscan2
- HYDIN | c.11506G>A p.E3836K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as COSV66637641; called by muse, mutect2, varscan2
- IGLV3-10 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs369446978; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.952); catalogued as COSV56242256; called by muse, mutect2, varscan2
- IL21R | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as rs913689113, COSV61968895; called by muse, mutect2, varscan2
- IL27 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as rs1000325951, COSV100112241; called by muse, mutect2, varscan2
- IL2RB | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as COSV53425195; called by muse, mutect2, varscan2
- INTU | c.1570T>C p.Y524H | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as COSV58869836; called by muse, varscan2
- IQGAP2 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV57168953; called by muse, mutect2, varscan2
- JAK2 | c.377G>A p.S126N | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV67584779; called by muse, mutect2, varscan2
- JCAD | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV64759905; called by muse, mutect2, varscan2
- JPH2 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1171598388, COSV65902053; called by muse, mutect2, varscan2
- KCNK13 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV56411029; called by muse, mutect2, varscan2
- KDM5C | c.2293G>A p.V765I | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV64763182; called by muse, mutect2, varscan2
- KIF11 | c.2847T>A p.D949E | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV53269043; called by muse, mutect2, varscan2
- KIF2C | c.1883C>T p.S628F | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64764034; called by muse, mutect2, varscan2
- KLHDC7A | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV68769154; called by muse, mutect2, varscan2
- LINGO4 | c.1670G>A p.W557* | Nonsense Mutation (SNP) | VAF 34/172 reads (20%) | catalogued as COSV64313512; called by muse, mutect2, varscan2
- LIPI | c.1004G>A p.R335K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.86); PolyPhen benign (0.036); catalogued as COSV60708893; called by muse, mutect2, varscan2
- LRP5 | c.3914G>A p.C1305Y | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53712136; called by muse, mutect2, varscan2
- LRRC3B | c.280A>G p.N94D | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV67520279; called by muse, mutect2
- LRRC3B | c.282C>A p.N94K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as COSV67520282; called by muse, mutect2
- LRRC7 | c.565G>A p.E189K (on ENST00000651989 / NM_001370785.2; = p.E156K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV50417577, COSV99229386; called by muse, mutect2
- LRTM2 | c.685A>T p.T229S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.024); catalogued as COSV54564128; called by muse, mutect2, varscan2
- MAGEE1 | c.2309G>A p.G770E | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.986); catalogued as COSV63909046; called by muse, mutect2, varscan2
- MAP2 | c.959G>A p.G320E | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.77); catalogued as COSV52280330, COSV52283270; called by muse, mutect2, varscan2
- MAPKBP1 | c.4102C>T p.P1368S (on ENST00000456763 / NM_001128608.2; = p.P1362S on NM_014994.3) | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs767592033, COSV52958657; called by muse, mutect2, varscan2
- MAPRE2 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.098); catalogued as rs1195269032, COSV55817850; called by muse, mutect2, varscan2
- MARCHF11 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60126559; called by muse, mutect2, varscan2
- MATN3 | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV68099464; called by muse, mutect2
- MCHR2 | c.695A>G p.K232R | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.098); catalogued as COSV56000338; called by muse, mutect2, varscan2
- MCM4 | c.913C>T p.Q305* | Nonsense Mutation (SNP) | VAF 17/75 reads (23%) | catalogued as COSV50621555; called by muse, mutect2, varscan2
- METTL27 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.075); catalogued as COSV52895085; called by muse, mutect2, varscan2
- MPZL2 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756473319, COSV54048400; called by muse, mutect2, varscan2
- MRC2 | c.3758G>A p.R1253Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.207); catalogued as rs754204879, COSV57637352; called by muse, mutect2, varscan2
- MROH2B | c.4371G>A p.M1457I | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV68181859; called by muse, mutect2, varscan2
- MUC16 | c.28246C>T p.P9416S | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.031); catalogued as COSV67449966; called by muse, mutect2, varscan2
- MYH7B | c.5338G>A p.A1780T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV52677428; called by muse, mutect2, varscan2
- MYO18B | c.3467G>A p.R1156K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770804583, COSV59127333; called by muse, mutect2
- MYO5A | c.3553C>T p.R1185C | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs751755968, COSV62557615; called by muse, mutect2, varscan2
- MYOM2 | c.4220G>A p.G1407D | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.272); catalogued as COSV50703618; called by muse, mutect2, varscan2
- NCAM2 | c.2446C>T p.P816S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV53059947; called by muse, mutect2, varscan2
- NEK1 | c.3035C>T p.S1012F | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV71454791; called by muse, mutect2, varscan2
- NFAM1 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.897); catalogued as COSV61194726; called by muse, mutect2, varscan2
- NHS | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs767477036, COSV66272179; called by muse, mutect2, varscan2
- NKAIN3 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV60651878; called by muse, mutect2
- NLGN1 | c.2352T>G p.I784M | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV64325135; called by muse, mutect2, varscan2
- NLRP7 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.91); catalogued as COSV60171709; called by muse, mutect2, varscan2
- NPC1L1 | c.3289C>T p.R1097* | Nonsense Mutation (SNP) | VAF 24/109 reads (22%) | catalogued as rs762878287, COSV56922963; called by muse, mutect2, varscan2
- NPR2 | c.1801C>T p.R601C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1563988849, CM156073, COSV61309508; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRK | c.3313G>A p.E1105K | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV54591220, COSV99688066; called by muse, mutect2, varscan2
- NUP155 | c.2722A>T p.S908C (on ENST00000231498 / NM_153485.3; = p.S849C on NM_004298.4) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV51527534; called by muse, mutect2
- OGFRL1 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.946); catalogued as COSV64971715; called by muse, mutect2, varscan2
- OLFM1 | c.611A>T p.Y204F (on ENST00000371793 / NM_001282611.2; = p.Y186F on NM_014279.5) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); catalogued as COSV99423133; called by muse, mutect2, varscan2
- OR10K1 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV56870724; called by muse, mutect2, varscan2
- OR11H1 | c.670C>T p.L224F | Missense Mutation (SNP) | VAF 83/218 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV53271630, COSV53271829; called by muse, varscan2
- OR11L1 | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.104); catalogued as COSV100869449, COSV63313807; called by muse, mutect2, varscan2
- OR4K13 | c.527G>A p.S176N | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.162); catalogued as COSV59859087; called by muse, mutect2, varscan2
- OR4K15 | c.515C>T p.S172L (on ENST00000305051; = p.S148L on NM_001005486.1) | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV59300549, COSV59300912; called by muse, mutect2, varscan2
- OR4Q3 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs867709774, COSV59177540, COSV59179709; called by muse, mutect2
- OR51A4 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV66749156; called by muse, mutect2, varscan2
- OR51D1 | c.225C>A p.F75L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV62913939, COSV62914844; called by muse, mutect2, varscan2
- OR51D1 | c.734G>A p.R245K | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV62913941; called by muse, mutect2, varscan2
- OR51M1 | c.41T>G p.L14R | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV60783946; called by muse, mutect2, varscan2
- OR56A1 | c.313T>C p.F105L | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV57361917; called by muse, mutect2, varscan2
- OR8B3 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1352350871, COSV63541334; called by muse, mutect2, varscan2
- OSBPL3 | c.2306T>C p.V769A | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV57653586; called by muse, mutect2
- PCDHB1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as COSV60629736; called by muse, mutect2, varscan2
- PCDHGA6 | c.1715C>T p.S572F | Missense Mutation (SNP) | VAF 85/361 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.762); catalogued as rs368947176; called by muse, mutect2, varscan2
- PCOLCE2 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs1432771965, COSV55997801; called by muse, mutect2, varscan2
- PDE1B | c.41A>T p.E14V | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.184); catalogued as COSV54490120; called by muse, mutect2
- PDE6A | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54925100; called by muse, mutect2, varscan2
- PGBD1 | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs768411095, COSV52551605; called by muse, mutect2, varscan2
- PIK3C2G | c.532A>G p.T178A | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV99849350; called by muse, varscan2
- PIP | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.238); catalogued as COSV52120088; called by muse, mutect2, varscan2
- PKD2L2 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51795174; called by muse, mutect2, varscan2
- PLA2R1 | c.609G>A p.W203* | Nonsense Mutation (SNP) | VAF 21/93 reads (23%) | catalogued as COSV51775664; called by muse, mutect2, varscan2
- PPARGC1A | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53525079; called by muse, mutect2, varscan2
- PPRC1 | c.2803C>T p.P935S | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV53383595; called by muse, mutect2, varscan2
- PTPRZ1 | c.822T>G p.Y274* | Nonsense Mutation (SNP) | VAF 21/82 reads (26%) | catalogued as COSV66431720; called by muse, mutect2, varscan2
- PUS7L | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61261334; called by muse, mutect2
- PXDN | c.1264C>T p.H422Y | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV53228125; called by muse, mutect2, varscan2
- RAB6D | c.646A>G p.T216A | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs765890129; called by muse, mutect2, varscan2
- RAD23B | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.379); catalogued as COSV100787594; called by muse, mutect2
- RB1 | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs587778640, COSV57297991; ClinVar: not provided / benign / likely benign; called by muse, mutect2, varscan2
- RECK | c.2393C>T p.S798F | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV65034786; called by muse, mutect2, varscan2
- RXFP1 | c.1793C>T p.S598F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV57047413; called by muse, mutect2
- SCN7A | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV69269335; called by muse, mutect2, varscan2
- SCN8A | c.5377G>A p.E1793K | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV61977466; called by muse, mutect2, varscan2
- SEMG2 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as COSV65647263, COSV65647834; called by muse, mutect2, varscan2
- SEZ6L2 | c.1444C>T p.R482C (on ENST00000308713 / NM_001114099.3; = p.R412C on NM_012410.4) | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.594); catalogued as rs1466762799, COSV58096772; called by muse, mutect2, varscan2
- SHROOM4 | c.1913C>G p.S638C | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs200014853, CM1515052, COSV56785499; called by muse, mutect2, varscan2
- SIGLEC11 | c.1357G>A p.V453M | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs369116394, COSV70221867; called by muse, mutect2, varscan2
- SLAIN1 | c.1553G>T p.R518L (on ENST00000466548; = p.R255L on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57385488, COSV57389537; called by muse, mutect2, varscan2
- SLC10A2 | c.558G>A p.W186* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as rs1446307653, COSV55357478; called by muse, mutect2, varscan2
- SLC14A2 | c.2707G>A p.E903K | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs773651739, COSV54906951; called by muse, mutect2, varscan2
- SLC6A19 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs375231132, COSV58669878; called by muse, mutect2, varscan2
- SLC6A7 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV100045949, COSV100046194; called by muse, mutect2, varscan2
- SLC9A2 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.285); catalogued as rs529065601, COSV52129399; called by muse, mutect2, varscan2
- SLIT3 | c.2899G>A p.G967R | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV60595323; called by muse, mutect2, varscan2
- SORCS3 | c.1780T>A p.S594T | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV63803820; called by muse, mutect2, varscan2
- SPINK5 | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs193173267, COSV56249808; called by muse, mutect2
- SRRM2 | c.5416T>G p.S1806A | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV57069317; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 18/66 reads (27%) | PolyPhen possibly damaging (0.776); catalogued as COSV52535094; called by muse, mutect2, varscan2
- STOX1 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373094820; called by muse, mutect2, varscan2
- TAF3 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs776762404, COSV60203882; called by muse, mutect2, varscan2
- TBC1D19 | c.473T>C p.F158S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV53514835; called by muse, mutect2, varscan2
- TDRD5 | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs762569393, COSV54238609; called by muse, mutect2
- TDRD6 | c.5760G>A p.M1920I | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1191925453, COSV60174239; called by muse, mutect2, varscan2
- TENM2 | c.3763G>A p.D1255N (on ENST00000518659 / NM_001122679.2; = p.D1023N on NM_001080428.3) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101317761; called by muse, mutect2, varscan2
- TFE3 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV59946126; called by muse, mutect2
- TGFBR2 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs371209879; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TGM4 | c.1728G>A p.M576I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV56093017; called by muse, mutect2, varscan2
- TLR5 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0.009); catalogued as rs1382633958, COSV60558133; called by muse, mutect2, varscan2
- TMEM132D | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV70596050; called by muse, mutect2
- TNC | c.3760G>A p.E1254K | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as COSV60781322, COSV60791155; called by muse, mutect2, varscan2
- TNNI3K | c.2261G>A p.G754E | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.121); catalogued as rs1486859057, COSV53946126; called by muse, mutect2, varscan2
- TOGARAM2 | c.1589A>G p.H530R | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65420134; called by muse, mutect2, varscan2
- TPTE | c.447-1G>A p.X149_splice (on ENST00000618007 / NM_199261.4; = p.X131_splice on NM_199259.4) | Splice Site (SNP) | VAF 8/79 reads (10%) | catalogued as rs749518352; called by muse, mutect2, varscan2
- TRANK1 | c.7690C>T p.P2564S | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1427799707, COSV57143081; called by muse, mutect2, varscan2
- TRIM36 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as rs759529085, COSV56688556; called by muse, mutect2, varscan2
- TRIM6 | c.1279A>C p.T427P | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV53474902; called by muse, mutect2, varscan2
- TRPC5 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 89/362 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.547); catalogued as COSV53285594; called by muse, mutect2, varscan2
- TRPV5 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 19/100 reads (19%) | catalogued as COSV54683556; called by muse, mutect2, varscan2
- TTC29 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV57272346; called by muse, mutect2, varscan2
- TTLL3 | c.2017C>T p.R673W | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs373701212, COSV100047150; called by muse, mutect2, varscan2
- TTLL6 | c.2461G>A p.E821K (on ENST00000393382 / NM_001130918.3; = p.E514K on NM_173623.3) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as rs757784001, COSV64976438; called by muse, mutect2, varscan2
- TTN | c.70328G>A p.R23443Q (on ENST00000591111; = p.R16019Q on NM_003319.4) | Missense Mutation (SNP) | VAF 29/119 reads (24%) | PolyPhen possibly damaging (0.587); catalogued as rs794729496, COSV59915666, COSV60099677; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBE3C | c.3064C>T p.P1022S | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61951701; called by muse, mutect2, varscan2
- UGT3A1 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs754987941, COSV57095662, COSV57098440; called by muse, mutect2, varscan2
- UNC5D | c.751+1G>A p.X251_splice | Splice Site (SNP) | VAF 11/38 reads (29%) | catalogued as COSV54774109; called by muse, mutect2, varscan2
- UNK | c.710A>G p.Y237C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV53139836; called by muse, mutect2
- USF3 | c.2777C>T p.P926L | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.046); catalogued as rs767764500, COSV57070380; called by muse, mutect2, varscan2
- USF3 | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as COSV57070390; called by muse, mutect2, varscan2
- USH2A | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV56335473; called by muse, mutect2, varscan2
- USP25 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV53481816; called by muse, mutect2, varscan2
- USP47 | c.4061C>T p.P1354L (on ENST00000399455 / NM_001372095.1; = p.P1266L on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59693881; called by muse, mutect2, varscan2
- VCAN | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV54098609; called by muse, mutect2, varscan2
- VNN1 | c.1055G>A p.G352E | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV63389436; called by muse, mutect2, varscan2
- VPS8 | c.4279G>A p.E1427K (on ENST00000625842 / NM_001349294.1; = p.E1425K on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV54981352; called by muse, mutect2, varscan2
- VWA2 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as rs190448182, COSV53905245; called by muse, mutect2, varscan2
- VWA3A | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as rs867406559, COSV55388520; called by muse, mutect2, varscan2
- WASHC5 | c.608G>A p.R203K | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.92); catalogued as rs573689796, COSV59194515; called by muse, mutect2
- ZAP70 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.076); catalogued as COSV53852946; called by muse, mutect2, varscan2
- ZDHHC23 | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 49/225 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1365972812, COSV57628833; called by muse, mutect2, varscan2
- ZFC3H1 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66430627; called by muse, mutect2, varscan2
- ZFHX4 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs769544985, COSV50553126; called by muse, mutect2, varscan2
- ZNF142 | c.1259A>T p.H420L (on ENST00000411696 / NM_001379660.1; = p.H220L on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV101376895; called by muse, mutect2, varscan2
- ZNF189 | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as COSV52274465; called by muse, mutect2, varscan2
- ZNF251 | c.1613C>T p.P538L | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99478121; called by muse, mutect2
- ZNF251 | c.1612C>T p.P538S | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs756744977, COSV52958414; called by muse, mutect2
- ZNF257 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV71306327; called by muse, mutect2, varscan2
- ZNF267 | c.1540C>T p.H514Y | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV56250974; called by muse, mutect2, varscan2
- ZNF454 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV60767152; called by muse, mutect2, varscan2
- ZNF572 | c.46A>T p.M16L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100073787; called by muse, mutect2, varscan2
- ZNF711 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.034); catalogued as COSV52151920, COSV99341341; called by muse, mutect2, varscan2
- ZNF813 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.047); catalogued as COSV101124681, COSV101124835; called by muse, mutect2, varscan2
- CD276 | c.1133del p.T378Rfs*2 (on ENST00000318443 / NM_001024736.2; = p.T160Rfs*2 on NM_025240.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | called by mutect2, pindel*, varscan2
- DNAH9 | c.1119_1148del p.S374_L383del | In Frame Del (DEL) | VAF 11/80 reads (14%) | called by mutect2, pindel
- IGKV2D-30 | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- IGLV2-33 | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 173/426 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA31A1 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TTC21A | c.1207_1215+17del p.X403_splice | Splice Site (DEL) | VAF 9/71 reads (13%) | called by mutect2, pindel
- ACOX3 | c.780C>T p.F260= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs372351617; called by muse, mutect2, varscan2
- ADAMTS10 | c.1140G>A p.E380= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs1271835140, COSV54352599; called by muse, mutect2, varscan2
- ADAMTS9 | c.2679C>T p.P893= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as rs1401847798, COSV55776322; called by muse, mutect2, varscan2
- AQP4 | c.315G>A p.V105= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV101270485; called by muse, mutect2
- ARNT2 | c.396C>T p.F132= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs780074025, COSV57582294; called by muse, mutect2, varscan2
- ATP13A4 | c.309C>T p.L103= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV55066717; called by muse, mutect2, varscan2
- BHLHE22 | c.807C>T p.I269= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs764929269, COSV100417590; called by muse, mutect2, varscan2
- BTBD11 | c.2055G>A p.E685= (on ENST00000280758 / NM_001018072.2; = p.E222= on NM_001017523.2) | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as rs1369605210, COSV55018662; called by muse, mutect2, varscan2
- CACNA1F | c.5181C>T p.F1727= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV59903339; called by muse, mutect2
- CACNA1S | c.1347C>T p.I449= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as rs754689047, COSV62936960; called by muse, mutect2, varscan2
- CAV3 | c.219C>T p.Y73= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV57478580; called by muse, mutect2, varscan2
- CAVIN2 | c.531C>T p.S177= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs1166956976, COSV58423425; called by muse, mutect2, varscan2
- CCDC62 | c.1623C>T p.S541= | Silent (SNP) | VAF 56/239 reads (23%) | catalogued as COSV53431098; called by muse, mutect2, varscan2
- CD109 | c.4245T>G p.P1415= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV54646173; called by muse, mutect2, varscan2
- CDK1 | c.385T>C p.L129= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV57349081; called by muse, varscan2
- CEP350 | c.7797G>A p.E2599= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV62599453; called by muse, mutect2, varscan2
- CGN | c.1548A>G p.E516= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV54968508; called by muse, mutect2, varscan2
- CHRM3 | c.1257T>C p.S419= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV55082057; called by muse, mutect2, varscan2
- CHST9 | c.1104G>A p.G368= | Silent (SNP) | VAF 23/114 reads (20%) | catalogued as COSV52429061; called by muse, mutect2, varscan2
- CLCA1 | c.1884C>T p.A628= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV52325643; called by muse, mutect2, varscan2
- CLEC9A | c.9G>A p.E3= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs371881201; called by muse, mutect2, varscan2
- COL6A2 | c.1647G>A p.G549= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as rs1339352133, COSV56000459; called by muse, mutect2, varscan2
- CPXM2 | c.2139G>A p.R713= | Silent (SNP) | VAF 36/168 reads (21%) | catalogued as COSV53864331, COSV99581002; called by muse, mutect2, varscan2
- DOCK1 | c.2337C>T p.I779= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as COSV54732040; called by muse, mutect2
- EVA1A | c.348G>A p.E116= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV52057075; called by muse, mutect2, varscan2
- EVC | c.1953C>T p.L651= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV53829842; called by muse, mutect2, varscan2
- EVPL | c.1602G>A p.L534= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV56908243; called by muse, mutect2, varscan2
- FAM114A1 | c.1572C>T p.I524= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs1426418288, COSV62672102; called by muse, mutect2, varscan2
- FARP1 | c.2283C>T p.I761= | Silent (SNP) | VAF 27/122 reads (22%) | catalogued as COSV60331408; called by muse, mutect2, varscan2
- FGF14 | c.510C>T p.A170= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV65937065; called by muse, mutect2, varscan2
- FLG | c.10113C>T p.S3371= | Silent (SNP) | VAF 255/557 reads (46%) | catalogued as rs141599535, COSV100912231; called by muse, mutect2, varscan2
- FMNL3 | c.3078C>T p.P1026= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV53300318; called by muse, mutect2
- FRMPD4 | c.798G>A p.Q266= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV101042107, COSV66216627; called by muse, mutect2, varscan2
- FSTL4 | c.2307G>A p.G769= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV54765214; called by muse, mutect2, varscan2
- FYB1 | c.2203C>T p.L735= (on ENST00000351578 / NM_199335.5; = p.L781= on NM_001465.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs747397676, COSV60941926; called by muse, mutect2
- FYB1 | c.1728G>A p.L576= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs761645401, COSV60941952; called by muse, mutect2, varscan2
- GIMAP8 | c.138C>T p.I46= | Silent (SNP) | VAF 41/210 reads (20%) | catalogued as COSV56230085; called by muse, mutect2, varscan2
- GPRC6A | c.1815C>T p.I605= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as COSV59951894; called by muse, mutect2, varscan2
- GUCY1A1 | c.993C>T p.I331= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV56650862; called by muse, mutect2, varscan2
- H3C8 | c.276C>T p.A92= | Silent (SNP) | VAF 32/169 reads (19%) | catalogued as rs1339702613, COSV100010389, COSV59952696; called by muse, mutect2, varscan2
- HIC1 | c.57G>A p.T19= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as rs927604650, COSV53963792; called by muse, mutect2
- IGFALS | c.54G>A p.V18= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV51904937; called by muse, mutect2
- IGKV1-16 | c.36C>T p.L12= | Silent (SNP) | VAF 36/161 reads (22%) | catalogued as rs527526347; called by muse, mutect2, varscan2
- IL27 | c.192G>A p.Q64= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV100112242, COSV60489074; called by muse, mutect2, varscan2
- IMPA2 | c.546C>T p.T182= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as COSV52318862; called by muse, mutect2, varscan2
- ITGAD | c.2367C>T p.T789= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as COSV66756976; called by muse, mutect2, varscan2
- JCAD | c.1068C>T p.P356= | Silent (SNP) | VAF 34/184 reads (18%) | catalogued as COSV100948052; called by muse, mutect2, varscan2
- JRK | c.291C>T p.F97= | Silent (SNP) | VAF 21/33 reads (64%) | catalogued as COSV70629581; called by muse, mutect2, varscan2
- KCNH6 | c.387C>T p.F129= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as rs757941229, COSV59001207; called by muse, mutect2, varscan2
- KCNMA1 | c.756C>T p.F252= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV54232200, COSV54266920; called by muse, mutect2, varscan2
- KEL | c.312C>T p.F104= | Silent (SNP) | VAF 24/107 reads (22%) | catalogued as COSV62333633; called by muse, mutect2, varscan2
- KIF7 | c.3591G>A p.L1197= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as COSV51538583; called by muse, mutect2, varscan2
- KLF10 | c.972C>T p.P324= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as rs545305135, COSV53434895; called by muse, mutect2, varscan2
- KLHDC7A | c.1911C>T p.F637= | Silent (SNP) | VAF 22/32 reads (69%) | catalogued as rs763993728, COSV68769147; called by muse, mutect2, varscan2
- KMT2C | c.960C>T p.F320= | Silent (SNP) | VAF 9/95 reads (9%) | catalogued as COSV51356870; called by muse, mutect2
- KRT3 | c.1131G>A p.Q377= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV58814839; called by muse, mutect2, varscan2
- LAMA3 | c.2947C>T p.L983= | Silent (SNP) | VAF 37/256 reads (14%) | catalogued as COSV58063491; called by muse, mutect2, varscan2
- LAMA5 | c.10548C>T p.G3516= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as rs763803853, COSV53354267; called by muse, mutect2, varscan2
- MAGEC1 | c.2373C>T p.L791= | Silent (SNP) | VAF 59/286 reads (21%) | catalogued as COSV53569071; called by muse, mutect2, varscan2
- MALL | c.69C>T p.F23= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as rs1275299241, COSV55600123; called by muse, mutect2
- MAST1 | c.2697G>A p.E899= | Silent (SNP) | VAF 64/158 reads (41%) | catalogued as rs1390418987, COSV52242142; called by muse, mutect2, varscan2
- MC3R | c.294C>T p.I98= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs748895410, COSV54763185; called by muse, mutect2, varscan2
- MOGS | c.945G>A p.G315= | Silent (SNP) | VAF 42/196 reads (21%) | catalogued as COSV51968454; called by muse, mutect2, varscan2
- MROH5 | c.3723C>T p.L1241= | Silent (SNP) | VAF 29/154 reads (19%) | catalogued as COSV61471217; called by muse, mutect2, varscan2
- MRPS18A | c.336C>T p.H112= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs144606291; called by muse, mutect2, varscan2
- MSLN | c.801C>T p.I267= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs754264983, COSV53499677; called by muse, mutect2
- MTMR14 | c.1404C>T p.V468= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV56003728; called by muse, mutect2, varscan2
- MUC16 | c.26049G>A p.G8683= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as COSV67449976; called by muse, mutect2, varscan2
- MUC16 | c.21765G>A p.V7255= | Silent (SNP) | VAF 64/131 reads (49%) | catalogued as COSV67449991; called by muse, mutect2, varscan2
- MUC5B | c.11106G>A p.T3702= | Silent (SNP) | VAF 61/387 reads (16%) | catalogued as rs1221219675, COSV71590411; called by muse, mutect2, varscan2
- MYBPC3 | c.3039C>T p.P1013= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV57023963; called by muse, mutect2, varscan2
- MYLK4 | c.708G>A p.V236= | Silent (SNP) | VAF 32/187 reads (17%) | catalogued as COSV51138896; called by muse, mutect2, varscan2
- MYO3A | c.4203G>A p.E1401= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs772688870, COSV56321998, COSV56348301; called by muse, mutect2, varscan2
- MYO5A | c.3552C>T p.L1184= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as COSV100697279; called by muse, mutect2, varscan2
- MYOCD | c.798C>T p.H266= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as rs764096193, COSV58498455; called by muse, mutect2, varscan2
- NCKAP5 | c.4839G>A p.T1613= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs1178447718, COSV58426697; called by muse, mutect2, varscan2
- NCKIPSD | c.1221G>A p.E407= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV53659986; called by muse, mutect2, varscan2
- NCOR2 | c.5991G>A p.K1997= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV62294272; called by muse, mutect2
- NDRG2 | c.858C>T p.L286= (on ENST00000298687 / NM_001354570.1; = p.L272= on NM_016250.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs765903094, COSV53871908; called by muse, mutect2, varscan2
- NEIL1 | c.295C>T p.L99= | Silent (SNP) | VAF 7/85 reads (8%) | catalogued as rs1156673222, COSV61833135; called by muse, mutect2
- NEK7 | c.765C>T p.Y255= | Silent (SNP) | VAF 15/125 reads (12%) | catalogued as COSV66314292; called by muse, mutect2, varscan2
- NR0B1 | c.954G>A p.Q318= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as CD087226, COSV66763683; called by muse, mutect2, varscan2
- NRXN3 | c.1695C>T p.F565= (on ENST00000335750 / NM_001330195.2; = p.F192= on NM_004796.6) | Silent (SNP) | VAF 45/179 reads (25%) | catalogued as COSV59720097; called by muse, mutect2, varscan2
- NUP155 | c.2724C>T p.S908= (on ENST00000231498 / NM_153485.3; = p.S849= on NM_004298.4) | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV51527527; called by muse, mutect2
- OLFM1 | c.612C>T p.Y204= (on ENST00000371793 / NM_001282611.2; = p.Y186= on NM_014279.5) | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs766788740, COSV99423139; called by muse, mutect2, varscan2
- OR10J1 | c.273C>T p.P91= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV71128282; called by muse, mutect2, varscan2
- OR2AE1 | c.852G>A p.L284= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as COSV60389790; called by muse, mutect2, varscan2
- OR4A15 | c.273C>T p.S91= | Silent (SNP) | VAF 28/128 reads (22%) | catalogued as rs200584338, COSV59033861; called by muse, mutect2, varscan2
- OR4D9 | c.753C>T p.F251= | Silent (SNP) | VAF 65/298 reads (22%) | catalogued as rs771977144, COSV61434214; called by muse, mutect2, varscan2
- OR4E2 | c.138C>T p.I46= | Silent (SNP) | VAF 44/170 reads (26%) | catalogued as COSV57731459; called by muse, varscan2
- OR4E2 | c.279C>T p.S93= | Silent (SNP) | VAF 49/162 reads (30%) | catalogued as COSV57731462; called by muse, varscan2
- OR4P4 | c.789C>T p.F263= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as rs746906978, COSV58920906, COSV58922157; called by muse, mutect2, varscan2
- OR4Q3 | c.738C>T p.F246= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as COSV59177529; called by muse, mutect2, varscan2
- OR4X2 | c.456C>T p.I152= | Silent (SNP) | VAF 41/202 reads (20%) | catalogued as COSV56582469; called by muse, mutect2, varscan2
- OR5B12 | c.453C>T p.F151= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as rs1201627555, COSV56904145; called by muse, mutect2, varscan2
- PCDHA11 | c.102C>T p.S34= | Silent (SNP) | VAF 54/162 reads (33%) | catalogued as COSV56482014; called by muse, mutect2, varscan2
- PCDHB14 | c.1260G>A p.T420= | Silent (SNP) | VAF 40/185 reads (22%) | catalogued as COSV53386901, COSV53391340; called by muse, mutect2, varscan2
- PCDHB3 | c.2148G>A p.R716= | Silent (SNP) | VAF 52/295 reads (18%) | catalogued as COSV50564861; called by muse, mutect2, varscan2
- PCDHB5 | c.720C>T p.P240= | Silent (SNP) | VAF 60/382 reads (16%) | catalogued as COSV50647861; called by muse, mutect2, varscan2
- PCDHB8 | c.1375C>T p.L459= | Silent (SNP) | VAF 68/706 reads (10%) | catalogued as COSV50755900; called by muse, mutect2
- PHF21B | c.1245C>T p.I415= | Silent (SNP) | VAF 41/229 reads (18%) | catalogued as rs1184659216, COSV57556428; called by muse, mutect2, varscan2
- PKDCC | c.1296C>T p.S432= | Silent (SNP) | VAF 20/143 reads (14%) | catalogued as COSV54306054; called by muse, mutect2, varscan2
- PLA2R1 | c.2274C>T p.V758= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV51775655; called by muse, mutect2, varscan2
- PLEK | c.774G>A p.R258= | Silent (SNP) | VAF 48/171 reads (28%) | catalogued as COSV52250803; called by muse, mutect2, varscan2
- PLOD2 | c.1437G>A p.R479= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV51462735; called by muse, mutect2, varscan2
- PLXDC2 | c.750C>T p.L250= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV65901423; called by muse, mutect2, varscan2
- PTPRS | c.3069C>T p.P1023= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as rs1395042194, COSV53612028; called by muse, mutect2, varscan2
- RAB8B | c.603C>T p.F201= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV58489162, COSV58489170; called by muse, mutect2, varscan2
- RAD23B | c.714G>A p.V238= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs746759493, COSV100787591; called by muse, mutect2
- RET | c.2469G>A p.G823= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV60688238; called by muse, mutect2, varscan2
- RET | c.2832C>T p.I944= | Silent (SNP) | VAF 41/192 reads (21%) | catalogued as rs755606269, COSV60688261, COSV60689830; called by muse, mutect2, varscan2
- SCGN | c.399C>T p.F133= | Silent (SNP) | VAF 33/187 reads (18%) | catalogued as rs1321608498, COSV58544601; called by muse, mutect2, varscan2
- SHANK1 | c.6357C>T p.F2119= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV53244442; called by muse, mutect2, varscan2
- SIRPB1 | c.180C>T p.I60= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as COSV53537725; called by muse, mutect2, varscan2
- SLC22A16 | c.1305C>T p.I435= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV57927842; called by muse, mutect2, varscan2
- SLC25A16 | c.846C>T p.T282= | Silent (SNP) | VAF 26/141 reads (18%) | catalogued as rs753536129, COSV56264086; called by muse, mutect2, varscan2
- SLC6A7 | c.1245C>T p.F415= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV100045948; called by muse, mutect2, varscan2
- SPEM2 | c.1326G>A p.P442= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs371497094; called by muse, mutect2, varscan2
- SRCAP | c.7743C>T p.P2581= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV52668458; called by muse, mutect2, varscan2
- TACC2 | c.5868G>A p.P1956= (on ENST00000334433; = p.P34= on NM_006997.4) | Silent (SNP) | VAF 34/136 reads (25%) | catalogued as rs750095297, COSV53277160; called by muse, mutect2, varscan2
- TCERG1L | c.411C>T p.V137= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs781180756, COSV64047385, COSV64058593; called by muse, mutect2, varscan2
- TMEM119 | c.645G>A p.G215= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV67188477; called by muse, mutect2, varscan2
- TRBV27 | c.344C>T p.*115= | Silent (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- TRERF1 | c.3393G>A p.T1131= | Silent (SNP) | VAF 102/416 reads (25%) | catalogued as rs755662837, COSV61667940; called by muse, mutect2, varscan2
- TSHB | c.199C>T p.L67= | Silent (SNP) | VAF 33/146 reads (23%) | catalogued as rs1469905326, COSV56654895; called by muse, mutect2, varscan2
- TTLL3 | c.2016C>T p.I672= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV100047147; called by muse, mutect2, varscan2
- UNC5D | c.1374C>T p.I458= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV54774132; called by muse, mutect2, varscan2
- USP25 | c.3078G>A p.P1026= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs755413104, COSV53481832; called by muse, mutect2, varscan2
- USP43 | c.2466G>A p.K822= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV53300276; called by muse, mutect2, varscan2
- VCAN | c.6942C>T p.L2314= | Silent (SNP) | VAF 43/114 reads (38%) | catalogued as rs867330334, COSV54098622; called by muse, mutect2, varscan2
- ZBTB7B | c.1311G>A p.K437= (on ENST00000292176; = p.K471= on NM_001252406.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as COSV52691698; called by muse, mutect2, varscan2
- ZDBF2 | c.930G>A p.P310= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs377262471; called by mutect2, varscan2
- ZFP2 | c.225C>T p.N75= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV63724843; called by muse, mutect2, varscan2
- ZGRF1 | c.1122C>T p.F374= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as rs775473648, COSV52199238; called by mutect2, varscan2
- ZMIZ1 | c.1521C>T p.Y507= | Silent (SNP) | VAF 39/214 reads (18%) | catalogued as COSV100565945, COSV57890825; called by muse, mutect2, varscan2
- ZNF142 | c.1260C>T p.H420= (on ENST00000411696 / NM_001379660.1; = p.H220= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV101376894; called by muse, mutect2, varscan2
- ZNF224 | c.372C>T p.F124= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV61241707; called by muse, mutect2, varscan2
- AC073310.1 | n.277G>A | RNA (SNP) | VAF 20/161 reads (12%) | called by muse, mutect2, varscan2
- AL133467.5 | chr14:95665022 G>A | 3'Flank (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2
- DCAF13 | chr8:103415307 T>C | 5'Flank (SNP) | VAF 23/152 reads (15%) | catalogued as COSV52566922; called by muse, mutect2, varscan2
- USP6 | c.1079-148C>T | Intron (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100002976; called by muse, mutect2
- VPS26C | chr21:37221367 A>G | 3'Flank (SNP) | VAF 15/63 reads (24%) | called by muse, mutect2, varscan2
- ZNF467 | chr7:149776988 C>T | 5'Flank (SNP) | VAF 28/88 reads (32%) | catalogued as rs796848519, COSV50486632, COSV50487906; called by muse, mutect2, varscan2
